Somatic mutation profile of tumor specimen TCGA-43-8116-01A (aliquot TCGA-43-8116-01A-11D-2244-08) from TCGA case TCGA-43-8116, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.3 years (26,790 days).
Specimen TCGA-43-8116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d242beb-29e6-4b72-9073-c438f09d2886.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-8116-10A (Blood Derived Normal), aliquot TCGA-43-8116-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0ef6914-26c0-47bc-87fa-8e2614a2dbef

The open-access MAF lists 397 somatic variants for this specimen: 291 protein-altering or splice-affecting, 96 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 96, Nonsense Mutation 15, Frame Shift Del 8, Intron 6, Frame Shift Ins 2, RNA 2, Splice Region 2, 5'UTR 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8970A>G p.I2990M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.384); catalogued as rs564678491, COSV101447153; called by muse, mutect2, varscan2
- ACRBP | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as COSV99976248; called by muse, mutect2
- ACTR1B | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008174; called by muse, mutect2, varscan2
- ADAMTS10 | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99546509, COSV99547325; called by muse, mutect2, varscan2
- ADAMTS20 | c.2411C>A p.A804E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.06); catalogued as COSV101166377; called by muse, mutect2, varscan2
- ADGRL4 | c.749C>A p.S250* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100876443, COSV66062783; called by muse, mutect2, varscan2
- AGXT2 | c.1383T>G p.H461Q | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV99183851; called by muse, mutect2, varscan2
- ANK2 | c.3557G>T p.G1186V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100003578, COSV52156495; called by muse, mutect2, varscan2
- APLNR | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 136/272 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99951610; called by muse, mutect2, varscan2
- ARID4A | c.1363A>C p.S455R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV100794577; called by muse, mutect2, varscan2
- ASTN2 | c.1889G>A p.R630K (on ENST00000313400 / NM_001365069.1; = p.R579K on NM_014010.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100529740; called by muse, mutect2, varscan2
- ATN1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 451/749 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV100755933; called by muse, mutect2, varscan2
- ATP2B3 | c.2267G>T p.W756L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99685529; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1871A>G p.Y624C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100023539; called by muse, mutect2, varscan2
- ATP8B3 | c.963A>T p.E321D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.516); catalogued as COSV100034856; called by muse, mutect2, varscan2
- AXDND1 | c.1672G>C p.G558R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100858597; called by muse, mutect2, varscan2
- BCL3 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 127/620 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99378289; called by muse, mutect2, varscan2
- BDP1 | c.7427G>T p.R2476I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100703426; called by muse, mutect2, varscan2
- BOD1L1 | c.4744G>C p.E1582Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99240120; called by muse, mutect2, varscan2
- BRF2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99605089; called by muse, mutect2, varscan2
- BSX | c.410C>G p.T137R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100545308; called by muse, mutect2, varscan2
- C11orf87 | c.443C>G p.S148W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs758116201, COSV100535876; called by muse, mutect2, varscan2
- C18orf21 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99321661; called by muse, mutect2, varscan2
- C1S | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV100196745; called by muse, mutect2
- C6 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV99667626; called by muse, mutect2, varscan2
- CALCR | c.694C>A p.P232T (on ENST00000649521 / NM_001164737.2; = p.P216T on NM_001742.4) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100810800; called by muse, mutect2, varscan2
- CCDC33 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 4/81 reads (5%) | catalogued as COSV99173527; called by muse, mutect2
- CCDC59 | c.289T>C p.Y97H | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810779; called by muse, mutect2, varscan2
- CCDC71 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1329889633, COSV100422424; called by muse, mutect2, varscan2
- CDC20B | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99697277; called by muse, mutect2, varscan2
- CENPJ | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs776367665, COSV101121561; called by muse, mutect2, varscan2
- CENPS-CORT | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100471846; called by muse, mutect2, varscan2
- CHAF1B | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100023726; called by muse, mutect2
- CHAT | c.1819del p.Q607Rfs*9 | Frame Shift Del (DEL) | VAF 47/169 reads (28%) | catalogued as COSV60321610, COSV60321841; called by mutect2, pindel, varscan2
- CHRM2 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV57782890, COSV57784898; called by muse, mutect2, varscan2
- CLIP1 | c.2483G>C p.R828T (on ENST00000620786 / NM_001247997.1; = p.R817T on NM_002956.2) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs778540801, COSV100212239; called by muse, mutect2, varscan2
- CLIP3 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99431252; called by muse, mutect2, varscan2
- CLK3 | c.1193A>G p.N398S (on ENST00000395066 / NM_001130028.1; = p.N250S on NM_003992.4) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100166124; called by muse, mutect2, varscan2
- CLMP | c.989C>A p.T330N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101507445, COSV71649200; called by muse, mutect2, varscan2
- CLVS1 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.926); catalogued as COSV100370508; called by muse, mutect2, varscan2
- CLVS1 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV100370511; called by muse, mutect2, varscan2
- COL14A1 | c.2148T>A p.F716L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99920330; called by muse, varscan2
- COL25A1 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101211611; called by muse, mutect2, varscan2
- CPB1 | c.1194C>A p.C398* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99294462; called by muse, mutect2, varscan2
- CPS1 | c.2306T>C p.M769T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99243846; called by muse, mutect2, varscan2
- CPS1 | c.2953C>G p.H985D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99243849; called by muse, mutect2, varscan2
- CRTAC1 | c.1800G>C p.E600D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV100086030; called by muse, mutect2, varscan2
- CSMD2 | c.5986T>C p.W1996R | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99594075; called by muse, mutect2, varscan2
- CSMD2 | c.4769T>G p.V1590G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV99594077; called by muse, mutect2, varscan2
- CSMD3 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99844346; called by muse, mutect2, varscan2
- CSRNP1 | c.1636G>T p.G546W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV99827065; called by muse, mutect2, varscan2
- CUEDC1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100804809; called by muse, mutect2
- DAAM2 | c.2545C>A p.L849M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.574); catalogued as COSV99226710; called by muse, mutect2, varscan2
- DCAF4L2 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs762635134, COSV100151209; called by muse, mutect2, varscan2
- DCSTAMP | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99886873; called by muse, mutect2, varscan2
- DDX1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); catalogued as rs753510952, COSV99246832; called by muse, mutect2, varscan2
- DNAH2 | c.9215T>G p.V3072G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV101209543; called by muse, mutect2, varscan2
- DNAH8 | c.7724C>A p.P2575H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59465301; called by muse, mutect2, varscan2
- DNAJB11 | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99408707; called by muse, mutect2, varscan2
- DNAJC13 | c.3943C>A p.H1315N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99607882; called by muse, varscan2
- DNAJC5B | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV52535695, COSV99395865; called by muse, mutect2, varscan2
- DOCK3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV56528149; called by muse, mutect2, varscan2
- DOK1 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs764963704, COSV99284170; called by muse, mutect2, varscan2
- DPP6 | c.1678C>T p.P560S (on ENST00000377770 / NM_001364500.2; = p.P498S on NM_001936.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100127529; called by muse, mutect2, varscan2
- ECT2 | c.2670del p.S891Pfs*16 (on ENST00000392692 / NM_001349098.2; = p.S860Pfs*16 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as COSV99222014; called by mutect2, varscan2
- ECT2L | c.2354T>A p.I785N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100872151; called by muse, mutect2, varscan2
- EDNRA | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV100163587; called by muse, mutect2, varscan2
- EIF2AK4 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV55469859, COSV99775247; called by muse, mutect2, varscan2
- ELMO1 | c.2143A>T p.K715* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100165627; called by muse, mutect2, varscan2
- ENO1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 41/519 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV99318963; called by muse, mutect2
- ENPP7 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV60386085; called by muse, mutect2, varscan2
- EPHA6 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV67568249; called by muse, mutect2, varscan2
- EXOC4 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.97); catalogued as rs1449139186, COSV99555196; called by muse, mutect2, varscan2
- EXOC4 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99555200; called by muse, mutect2, varscan2
- EXOSC7 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99652123; called by muse, mutect2, varscan2
- FAM135B | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52732717, COSV52744671; called by muse, mutect2, varscan2
- FAM163A | c.316T>A p.Y106N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100523138; called by muse, mutect2, varscan2
- FBN2 | c.7726G>T p.G2576W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV99330011; called by muse, mutect2, varscan2
- FBN2 | c.3965C>A p.T1322K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99330015; called by muse, mutect2, varscan2
- FLT1 | c.3680C>A p.T1227N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99165521; called by muse, mutect2, varscan2
- FUT10 | c.623G>C p.R208T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV100161684; called by muse, mutect2, varscan2
- FYB1 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs776659469, COSV100686113; called by muse, mutect2
- GALNT14 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as COSV61105373; called by muse, mutect2, varscan2
- GATA2 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100351489; called by muse, mutect2, varscan2
- GATAD2B | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64086045; called by muse, mutect2, varscan2
- GHR | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051597; called by muse, mutect2, varscan2
- GJA5 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99605768; called by muse, mutect2, varscan2
- GJD2 | c.830G>T p.W277L | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.232); catalogued as COSV99290851; called by muse, mutect2, varscan2
- GPT2 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100413031, COSV60837509; called by muse, mutect2, varscan2
- GRB10 | c.1651G>C p.G551R (on ENST00000398812; = p.G505R on NM_001001549.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100240928; called by muse, mutect2, varscan2
- GRIA3 | c.2656G>A p.V886M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99991401; called by muse, mutect2, varscan2
- GUCA1C | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53751676, COSV99659914; called by muse, mutect2, varscan2
- HCN3 | c.1400T>G p.F467C | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712998; called by muse, mutect2, varscan2
- HDAC10 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV99352630; called by muse, mutect2
- HGFAC | c.1466C>G p.S489W | Missense Mutation (SNP) | VAF 46/972 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368756601, COSV101237780; called by muse, mutect2
- HIBADH | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99607419; called by muse, mutect2, varscan2
- HIKESHI | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as COSV99563604; called by muse, mutect2, varscan2
- HOXA1 | c.422A>C p.Q141P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99761375; called by muse, mutect2, varscan2
- HPF1 | c.127A>G p.N43D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV101097687; called by muse, mutect2, varscan2
- HRH4 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.199); catalogued as COSV99907943, COSV99907994; called by muse, mutect2, varscan2
- HSPA12B | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99654178; called by muse, varscan2
- HSPA9 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.034); catalogued as COSV99785641; called by muse, mutect2
- HTR1E | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100541245; called by muse, mutect2, varscan2
- HTRA1 | c.1336A>G p.N446D | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100934789; called by muse, mutect2, varscan2
- IFNK | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs751052890, COSV99218841; called by muse, mutect2, varscan2
- IL7R | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV100286556; called by muse, mutect2, varscan2
- INPP5D | c.424G>T p.E142* (on ENST00000445964 / NM_001017915.3; = p.E141* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100856893, COSV64035749; called by muse, mutect2, varscan2
- ITPKC | c.1410G>T p.M470I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV99649021; called by muse, mutect2, varscan2
- JAK1 | c.3294G>C p.Q1098H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53809962, COSV99605542; called by muse, mutect2, varscan2
- JCHAIN | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs374027021, COSV99636587; called by muse, mutect2, varscan2
- KCTD8 | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV100759971; called by muse, mutect2, varscan2
- KDM5A | c.4636A>G p.K1546E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs1399725858, COSV101239031; called by muse, mutect2, varscan2
- KDR | c.3763G>A p.D1255N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99818450; called by muse, mutect2
- KIF13B | c.3562C>A p.L1188I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV101580784; called by muse, mutect2, varscan2
- KIF4B | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV101469375; called by muse, mutect2, varscan2
- KIRREL3 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1437300343, COSV69386350; called by muse, mutect2, varscan2
- KLHL41 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs368251922, COSV52929481; called by muse, mutect2, varscan2
- KLHL6 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.722); catalogued as COSV100384308, COSV100384960; called by muse, mutect2, varscan2
- KNTC1 | c.3422C>G p.T1141S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV100338682; called by muse, mutect2, varscan2
- KPNA1 | c.123A>T p.E41D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.152); catalogued as COSV100724346; called by muse, mutect2, varscan2
- KRT3 | c.1394A>G p.Q465R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.474); catalogued as COSV100527237; called by muse, mutect2, varscan2
- KRT72 | c.1191C>A p.H397Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53377357, COSV99537440; called by muse, mutect2, varscan2
- L3MBTL4 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99530581; called by muse, mutect2, varscan2
- LARP6 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100151013, COSV54582076; called by muse, mutect2, varscan2
- LCN1 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99704525; called by muse, mutect2, varscan2
- LCOR | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.192); catalogued as COSV99617105; called by muse, mutect2, varscan2
- LGMN | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.356); catalogued as COSV100605957; called by muse, mutect2, varscan2
- LILRA5 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100007058; called by muse, mutect2, varscan2
- LILRB5 | c.1467G>C p.R489S (on ENST00000449561 / NM_001081442.3; = p.R488S on NM_006840.5) | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as rs767241779, COSV100300710; called by muse, mutect2, varscan2
- LIPC | c.531del p.G178Afs*53 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | catalogued as COSV100134866; called by mutect2, pindel, varscan2
- LIPH | c.748A>T p.R250W | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99956258; called by muse, mutect2, varscan2
- LPIN2 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55245233; called by muse, mutect2, varscan2
- LRP1B | c.5599C>T p.L1867F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101259646; called by muse, mutect2, varscan2
- LRP1B | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101259648; called by muse, mutect2, varscan2
- LTK | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV99779256; called by muse, mutect2, varscan2
- LY6G6D | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV65419903; called by muse, mutect2, varscan2
- MAN1C1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.067); catalogued as rs753997245, COSV99848834; called by muse, mutect2, varscan2
- MBD1 | c.1106G>C p.R369P (on ENST00000269468 / NM_001323950.1; = p.R346P on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53998423, COSV54003378, COSV99497025; called by muse, mutect2, varscan2
- MC2R | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100563150; called by muse, mutect2, varscan2
- MCF2L2 | c.3145T>C p.C1049R | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100193649; called by muse, mutect2, varscan2
- MECOM | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101527949; called by muse, mutect2
- MEGF10 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.493); catalogued as COSV99175422; called by muse, mutect2, varscan2
- MEIS1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99715668; called by muse, mutect2, varscan2
- MIS18BP1 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100173202; called by muse, mutect2, varscan2
- MMRN1 | c.805T>A p.W269R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99307628; called by muse, mutect2, varscan2
- MMRN1 | c.806G>A p.W269* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99307630; called by muse, mutect2, varscan2
- MRM2 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99642747; called by muse, mutect2, varscan2
- MROH2B | c.4497G>T p.Q1499H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV101270877; called by muse, mutect2, varscan2
- MTOR | c.5740G>C p.G1914R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100816577, COSV63868893; called by muse, mutect2
- MUC16 | c.32329A>T p.S10777C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV101201061; called by muse, mutect2, varscan2
- MUC16 | c.23669G>T p.W7890L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); catalogued as COSV101201063; called by muse, mutect2, varscan2
- MUC20 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.415); catalogued as COSV100291455; called by muse, mutect2, varscan2
- MUC4 | c.2746A>G p.S916G | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.159); catalogued as COSV100641913; called by muse, mutect2, varscan2
- MYH2 | c.2477C>A p.S826Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1447040213, COSV55438104, COSV99820746; called by muse, mutect2, varscan2
- NCKAP1L | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53213288; called by muse, mutect2, varscan2
- NECTIN4 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100920020; called by muse, mutect2
- NFASC | c.2636C>T p.S879F (on ENST00000339876 / NM_001378329.1; = p.S982F on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV58385173; called by muse, mutect2, varscan2
- NIPA2 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100488691; called by muse, mutect2, varscan2
- NLRP3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60226163; called by muse, varscan2
- NLRP5 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV101173845; called by muse, mutect2, varscan2
- NLRP5 | c.2809G>T p.A937S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.53); catalogued as COSV101173846; called by mutect2, varscan2
- NLRP7 | c.810C>A p.C270* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100053207, COSV60172716; called by muse, mutect2, varscan2
- NME7 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100891135; called by muse, mutect2
- NNT | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99239418; called by muse, mutect2, varscan2
- NOTCH2 | c.5177G>A p.R1726H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1557804884, COSV99866254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5DC3 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1372160503, COSV101231021; called by muse, mutect2, varscan2
- NTRK2 | c.2032G>C p.A678P (on ENST00000323115 / NM_001369534.1; = p.A694P on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52859884, COSV99457953; called by muse, mutect2, varscan2
- NUP210L | c.4402C>T p.P1468S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV99668822; called by muse, mutect2, varscan2
- NUP214 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845374; called by muse, mutect2, varscan2
- OGDHL | c.2189G>T p.W730L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1036718892, COSV100934479; called by muse, mutect2, varscan2
- OR10G4 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100304942; called by muse, mutect2, varscan2
- OR10G9 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs779509683, COSV100901716; called by muse, mutect2, varscan2
- OR2G2 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100189929, COSV60739547; called by muse, mutect2, varscan2
- OR2H1 | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV101009906, COSV65810412; called by muse, mutect2, varscan2
- OR4D5 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.232); catalogued as COSV100190141; called by muse, mutect2, varscan2
- OR56A4 | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100417672; called by muse, mutect2, varscan2
- OR5F1 | c.346G>T p.G116W | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99558860; called by muse, varscan2
- OR5L1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 169/328 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV61735211; called by muse, mutect2, varscan2
- OR8K5 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); catalogued as rs776026222, COSV100537296, COSV57891585; called by muse, mutect2, varscan2
- ORC2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1036822880, COSV99309691; called by muse, mutect2, varscan2
- OSBPL1A | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1211720880, COSV60199449; called by muse, mutect2
- PADI1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs758706628, COSV100969241; called by muse, mutect2, varscan2
- PAN3 | c.2152A>G p.T718A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99145065; called by muse, mutect2, varscan2
- PAPPA | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100075041; called by muse, mutect2, varscan2
- PAX4 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490288; called by muse, mutect2, varscan2
- PAX5 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100814523; called by muse, mutect2, varscan2
- PCDH15 | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946296710, COSV100226003, COSV57265845, COSV57331271; called by muse, mutect2, varscan2
- PCDHA12 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.093); catalogued as COSV100253420; called by muse, mutect2, varscan2
- PCDHGA4 | c.2081C>A p.A694D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV99544754; called by muse, mutect2, varscan2
- PCDHGB3 | c.2055G>T p.Q685H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54025064, COSV99544757; called by muse, mutect2, varscan2
- PCK1 | c.350T>G p.M117R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV100100805; called by muse, mutect2, varscan2
- PCLO | c.11012C>G p.T3671R | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100436525, COSV61668178; called by muse, mutect2, varscan2
- PDE1C | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100370735; called by muse, mutect2, varscan2
- PDE4DIP | c.4409G>A p.W1470* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | catalogued as COSV100521070; called by muse, mutect2
- PDGFRA | c.2653C>G p.L885V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57264603, COSV99957418; called by muse, mutect2, varscan2
- PDHA2 | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV54779989; called by muse, mutect2, varscan2
- PDSS1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as COSV100873618; called by muse, mutect2, varscan2
- PDXDC1 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as COSV100363385; called by muse, mutect2, varscan2
- PIGG | c.2694G>T p.W898C (on ENST00000453061 / NM_001127178.3; = p.W890C on NM_017733.4) | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99574228; called by muse, mutect2, varscan2
- PLEC | c.2388G>A p.S796= (on ENST00000322810 / NM_201380.4; = p.S686= on NM_000445.5) | Splice Region (SNP) | VAF 16/111 reads (14%) | catalogued as rs536284705, COSV100517953; called by muse, mutect2, varscan2
- PLLP | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99536418; called by muse, mutect2, varscan2
- POGLUT1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD140068, COSV99809787; called by muse, mutect2, varscan2
- POLR3B | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57283616; called by muse, mutect2, varscan2
- PREPL | c.1372A>G p.M458V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as rs182854421; called by muse, mutect2, varscan2
- PRLR | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.772); catalogued as COSV99184702; called by muse, mutect2, varscan2
- PRLR | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.672); catalogued as COSV99184703; called by muse, mutect2, varscan2
- PROM2 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100468420; called by muse, mutect2, varscan2
- PRR30 | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV99574750; called by muse, mutect2, varscan2
- PTPRO | c.755T>C p.F252S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV99841453; called by muse, mutect2, varscan2
- RABGAP1L | c.2002T>C p.Y668H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99273427; called by muse, mutect2, varscan2
- RALYL | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); catalogued as rs749852603, COSV101569401; called by muse, mutect2, varscan2
- RBM24 | c.632C>G p.A211G (on ENST00000379052 / NM_001143942.2; = p.A166G on NM_153020.2) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV100553107; called by muse, mutect2
- RBP3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs782358403; called by muse, mutect2, varscan2
- REPIN1 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.995); catalogued as COSV101262677; called by muse, mutect2, varscan2
- REV3L | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs780640158, COSV100725589; called by muse, mutect2, varscan2
- RFPL3 | c.245C>A p.S82Y (on ENST00000249007 / NM_001098535.1; = p.S53Y on NM_006604.2) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.951); catalogued as COSV99967245; called by muse, mutect2, varscan2
- RGS8 | c.148G>T p.A50S (on ENST00000367556 / NM_001369564.2; = p.A68S on NM_033345.3) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV99276865; called by muse, mutect2, varscan2
- RNF20 | c.1231G>T p.G411C | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV101206566; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs368791535; ClinVar: benign; called by muse, mutect2, varscan2
- RUNX1T1 | c.768G>T p.E256D (on ENST00000265814 / NM_001198628.1; = p.E229D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56149757; called by muse, mutect2, varscan2
- SCML4 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV100940427; called by muse, mutect2, varscan2
- SCN10A | c.5451G>T p.E1817D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101479502; called by muse, mutect2, varscan2
- SCN10A | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1250337216, COSV101479503; called by muse, mutect2, varscan2
- SCRIB | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100253981; called by muse, mutect2, varscan2
- SDK2 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101168348; called by muse, varscan2
- SHOX2 | c.933G>C p.K311N (on ENST00000441443 / NM_006884.3; = p.K335N on NM_003030.4) | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101273819; called by muse, mutect2
- SI | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016777, COSV52296120; called by muse, mutect2, varscan2
- SI | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100016779; called by muse, mutect2, varscan2
- SIGLEC1 | c.4045G>T p.A1349S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as rs1277228074, COSV99170195; called by muse, mutect2, varscan2
- SLC22A8 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV100268044; called by muse, mutect2
- SLC25A16 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99770213; called by muse, mutect2, varscan2
- SLC26A8 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100839577; called by muse, mutect2, varscan2
- SLC47A2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs764308768, COSV99450167; called by muse, mutect2, varscan2
- SLC5A1 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833683; called by muse, mutect2, varscan2
- SMIM19 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100646189; called by muse, mutect2, varscan2
- SOGA1 | c.3506C>T p.S1169F | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1414146919, COSV52931384, COSV99415195; called by muse, mutect2, varscan2
- SORCS1 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV99549302; called by muse, mutect2, varscan2
- SPAM1 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99773341; called by muse, mutect2, varscan2
- SPICE1 | c.1867A>G p.N623D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99871673; called by muse, mutect2, varscan2
- STAM | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 9/211 reads (4%) | catalogued as COSV101098293; called by muse, mutect2
- STX4 | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV100572975; called by muse, mutect2, varscan2
- SVEP1 | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100990888; called by muse, mutect2, varscan2
- TBC1D20 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.178); catalogued as rs1343833741, COSV100830601; called by muse, mutect2, varscan2
- TBX22 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as COSV100960926; called by muse, mutect2, varscan2
- TCP1 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100365039; called by muse, mutect2, varscan2
- TDGF1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99947604; called by muse, mutect2, varscan2
- TDGF1 | c.428A>C p.Q143P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99947605; called by muse, mutect2, varscan2
- TENT5C | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV101033076; called by muse, mutect2, varscan2
- TMEM132D | c.1213T>A p.Y405N | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101399221, COSV101399536; called by muse, mutect2, varscan2
- TMEM151A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs939052973, COSV59173744; called by muse, mutect2, varscan2
- TMEM26 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99515794; called by muse, mutect2, varscan2
- TMEM38A | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs775502907, COSV99495056, COSV99495457; called by muse, mutect2, varscan2
- TMPRSS9 | c.837C>A p.F279L (on ENST00000648592; = p.F245L on NM_182973.2) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100211653; called by muse, mutect2
- TOX | c.1545G>T p.G515= | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100813061, COSV63845227; called by muse, mutect2, varscan2
- TRIM28 | c.1753C>G p.P585A | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99449355; called by muse, mutect2, varscan2
- TRPM8 | c.661T>A p.S221T | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100224434; called by muse, mutect2, varscan2
- TSPY2 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.845); catalogued as COSV100289208; called by muse, mutect2, varscan2
- TTN | c.39583A>T p.T13195S (on ENST00000591111; = p.T5771S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | PolyPhen benign (0.017); catalogued as COSV100625775; called by muse, mutect2, varscan2
- TTN | c.16265C>G p.T5422S (on ENST00000591111; = p.T4495S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | PolyPhen benign (0.005); catalogued as rs751087281, COSV100625780; called by muse, varscan2
- UACA | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100537677; called by muse, mutect2, varscan2
- UBE2Q2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932545634, COSV99143410; called by muse, mutect2, varscan2
- ULK2 | c.1957A>T p.R653W | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); catalogued as COSV100860939; called by muse, mutect2, varscan2
- UTRN | c.3452G>T p.R1151L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100840341; called by muse, mutect2, varscan2
- VAMP7 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV52901809, COSV99387994; called by muse, mutect2, varscan2
- WDR48 | c.464C>G p.S155* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100176849; called by muse, mutect2, varscan2
- XKR7 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs371180407; called by muse, mutect2, varscan2
- ZAN | c.6404G>A p.R2135H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs376133509, COSV100770159; called by muse, mutect2, varscan2
- ZDHHC5 | c.24A>T p.R8S | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99762577; called by muse, mutect2, varscan2
- ZFHX4 | c.9745G>T p.A3249S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99266450; called by muse, mutect2, varscan2
- ZFP69 | c.1444T>G p.F482V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV101018343; called by muse, mutect2, varscan2
- ZFR2 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.579); catalogued as COSV99507758; called by muse, mutect2, varscan2
- ZIM3 | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV54144802, COSV99518495; called by muse, mutect2, varscan2
- ZNF536 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62824937, COSV62832875; called by muse, mutect2, varscan2
- ZNF595 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100227867; called by muse, mutect2, varscan2
- ZNF671 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100235217; called by muse, mutect2, varscan2
- ZNF780A | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV100575211; called by muse, mutect2, varscan2
- ZXDC | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100306576; called by muse, mutect2, varscan2
- ZZZ3 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1408475948, COSV100890424; called by muse, mutect2
- AHNAK2 | c.2667_2668insTT p.L890Ffs*11 | Frame Shift Ins (INS) | VAF 24/151 reads (16%) | called by mutect2, varscan2*
- ANK1 | c.1440del p.I480Mfs*7 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- CFAP46 | c.495_496del p.Q165Hfs*2 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.1342del p.E448Kfs*7 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel
- FSHR | c.1475dup p.M492Ifs*32 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- GDE1 | c.848+1del p.X283_splice | Splice Site (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- LRP1B | c.2373del p.K791Nfs*10 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- MRC1 | c.2086C>A p.Q696K | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PRKDC | c.4015del p.V1339Sfs*11 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2921A>T p.E974V (on ENST00000621492; = p.E940V on NM_025248.3) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TG | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- UNC13A | c.1753_1761del p.T585_C587del | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ABCA13 | c.7200G>A p.E2400= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101447152; called by muse, mutect2, varscan2
- ABCB8 | c.1545C>A p.T515= (on ENST00000297504 / NM_001282291.2; = p.T498= on NM_007188.5) | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs148909212; called by muse, mutect2, varscan2
- ABCF2 | c.348C>G p.L116= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99734782; called by muse, mutect2, varscan2
- ABCG2 | c.1626C>A p.T542= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99419951; called by muse, mutect2, varscan2
- ADPRHL1 | c.807G>T p.G269= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100733515; called by muse, mutect2, varscan2
- ALMS1 | c.9351A>G p.L3117= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100043397; called by muse, mutect2
- ARHGAP32 | c.2898C>A p.A966= (on ENST00000310343 / NM_001378025.1; = p.A617= on NM_014715.4) | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100088863; called by muse, mutect2, varscan2
- ASAH2 | c.1428G>A p.G476= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- ASAH2B | c.54C>T p.S18= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV99485938; called by muse, mutect2, varscan2
- BRICD5 | c.279C>A p.I93= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100063925; called by muse, mutect2, varscan2
- C16orf78 | c.321T>C p.Y107= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100147910; called by muse, mutect2, varscan2
- CA5A | c.207C>A p.I69= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99990771; called by muse, mutect2
- CACNA1B | c.3681C>T p.V1227= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99499152; called by muse, mutect2, varscan2
- CD163L1 | c.3012C>A p.T1004= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV100550569; called by muse, mutect2, varscan2
- CDC20B | c.1317C>A p.I439= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99697278; called by muse, mutect2, varscan2
- CDO1 | c.372C>A p.V124= | Silent (SNP) | VAF 59/141 reads (42%) | catalogued as COSV51665673; called by muse, mutect2, varscan2
- CEP135 | c.1230T>C p.V410= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99954789; called by mutect2, varscan2
- CYBRD1 | c.762C>T p.G254= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100361453; called by muse, mutect2, varscan2
- CYP2E1 | c.1473C>A p.P491= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99428833; called by muse, mutect2, varscan2
- DELE1 | c.1329G>C p.L443= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99519978; called by muse, mutect2, varscan2
- DIP2B | c.4599C>T p.I1533= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs766200359, COSV56588979; called by muse, mutect2, varscan2
- DIS3L2 | c.1615T>C p.L539= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99807061; called by muse, mutect2, varscan2
- DTNA | c.306C>A p.I102= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV99314582; called by muse, mutect2, varscan2
- FBN2 | c.2508G>T p.T836= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs372872626, COSV99330019; called by muse, mutect2, varscan2
- FBXW9 | c.180G>C p.P60= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100790404; called by muse, mutect2, varscan2
- GABRB1 | c.1134G>C p.T378= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV99783020; called by muse, mutect2, varscan2
- GLYAT | c.234C>A p.I78= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as COSV99557230, COSV99557507; called by muse, mutect2, varscan2
- GNPAT | c.825C>G p.T275= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100791522, COSV100791688; called by muse, mutect2, varscan2
- GRM3 | c.612C>A p.I204= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100862488, COSV100862768; called by muse, mutect2, varscan2
- GRM6 | c.2058C>G p.V686= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99179829; called by muse, mutect2, varscan2
- HEPH | c.234T>C p.Y78= (on ENST00000343002; = p.Y132= on NM_138737.5) | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100295519; called by muse, mutect2, varscan2
- HOXA1 | c.423G>A p.Q141= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs1299300346, COSV99761374; called by muse, mutect2, varscan2
- KANSL1 | c.702C>G p.V234= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV52265972, COSV52275347; called by muse, mutect2
- KCTD1 | c.426C>T p.C142= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs896053709, COSV58683957; called by muse, mutect2, varscan2
- KCTD8 | c.450C>A p.V150= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100759975; called by muse, mutect2, varscan2
- KIF4B | c.1242C>A p.A414= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV101469374; called by muse, mutect2, varscan2
- KLK5 | c.763C>T p.L255= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100307166; called by muse, mutect2, varscan2
- LILRB4 | c.597C>T p.H199= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs758110982, COSV99554058; called by muse, varscan2
- LINS1 | c.1035G>T p.V345= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV100130455; called by muse, mutect2
- LPO | c.1800C>G p.L600= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV99229232; called by muse, mutect2, varscan2
- MAGI1 | c.288C>G p.A96= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV100442721, COSV58336682; called by muse, mutect2, varscan2
- MLX | c.417G>A p.Q139= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99519050; called by muse, mutect2, varscan2
- MMS22L | c.1491G>A p.K497= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99247569; called by muse, mutect2, varscan2
- MROH7 | c.408C>T p.A136= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100273923; called by muse, mutect2, varscan2
- MUC16 | c.14316T>A p.P4772= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV101201066; called by muse, mutect2, varscan2
- MUC17 | c.12144A>G p.S4048= | Silent (SNP) | VAF 57/232 reads (25%) | catalogued as COSV100074715; called by muse, mutect2, varscan2
- MUC4 | c.2745C>A p.T915= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs761141480, COSV100641917; called by muse, mutect2, varscan2
- MYF5 | c.402G>T p.L134= | Silent (SNP) | VAF 19/227 reads (8%) | catalogued as rs200169780; called by muse, mutect2
- NANOS2 | c.300G>T p.V100= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs905397777, COSV100379549; called by muse, mutect2, varscan2
- NID2 | c.15G>T p.R5= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99357103; called by muse, mutect2, varscan2
- NLRP3 | c.2736C>T p.L912= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60225390, COSV60226471; called by muse, mutect2
- NPTN | c.318C>G p.L106= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99766780; called by muse, mutect2, varscan2
- NRIP1 | c.2298T>C p.P766= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100013004; called by muse, mutect2, varscan2
- OBSCN | c.3169A>C p.R1057= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99482947; called by muse, mutect2, varscan2
- OR3A1 | c.253T>C p.L85= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs943455092, COSV100041811; called by muse, mutect2, varscan2
- OR4L1 | c.291C>T p.C97= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as rs375250646; called by muse, mutect2, varscan2
- OR5M11 | c.228T>C p.N76= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV101602060; called by muse, mutect2, varscan2
- OR7D4 | c.792G>T p.V264= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100432732; called by muse, mutect2, varscan2
- PADI3 | c.1434C>T p.V478= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs546789084, COSV100968567; called by muse, mutect2
- PCDHA12 | c.1941G>T p.L647= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs540811233, COSV99169275; called by muse, mutect2, varscan2
- PDZRN4 | c.924G>T p.V308= (on ENST00000402685 / NM_001164595.2; = p.V50= on NM_013377.4) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100115278; called by muse, mutect2, varscan2
- PLXNA4 | c.1818G>T p.V606= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100326384; called by muse, mutect2, varscan2
- PNPLA8 | c.1494C>T p.P498= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1254890504, COSV99993718; called by muse, mutect2, varscan2
- PRDM14 | c.426G>T p.P142= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV52571178, COSV99400433; called by muse, mutect2, varscan2
- PRPF8 | c.2565G>A p.R855= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100517808; called by muse, varscan2
- PRSS1 | c.528T>A p.P176= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV100298354; called by muse, mutect2, varscan2
- PRTG | c.3054A>G p.L1018= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV101221465; called by muse, mutect2
- PURA | c.255C>T p.F85= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100495780; called by muse, mutect2, varscan2
- RELN | c.8580C>T p.C2860= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as rs778305016, COSV100634572; called by muse, mutect2, varscan2
- SLAMF9 | c.357C>A p.I119= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV63637309; called by muse, mutect2, varscan2
- SLC39A12 | c.1899C>A p.I633= (on ENST00000377369 / NM_001145195.2; = p.I596= on NM_152725.3) | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs1479768480, COSV66195027; called by muse, mutect2, varscan2
- SLITRK3 | c.2151C>T p.G717= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs778426053, COSV53845485; called by muse, mutect2, varscan2
- SNTG1 | c.177C>T p.T59= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52473956, COSV99385469; called by muse, mutect2, varscan2
- SOGA3 | c.1843C>T p.L615= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV100847028; called by muse, mutect2, varscan2
- SPIDR | c.2466G>T p.R822= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs377584783; called by muse, mutect2, varscan2
- SPPL2A | c.594G>A p.L198= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1447800179, COSV55939623; called by muse, mutect2, varscan2
- SPRR2E | c.60G>A p.T20= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs200625311, COSV64203728; called by muse, mutect2, varscan2
- SPSB4 | c.771C>A p.I257= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100141654; called by muse, mutect2
- SV2C | c.90G>A p.V30= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100456673; called by muse, mutect2, varscan2
- TAS2R8 | c.907A>C p.R303= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99553932; called by muse, mutect2, varscan2
- TBK1 | c.1279A>C p.R427= | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as COSV100538346; called by muse, mutect2
- TCN2 | c.675A>T p.T225= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99308747; called by muse, mutect2, varscan2
- TET1 | c.5940G>C p.L1980= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as COSV101018768; called by muse, mutect2, varscan2
- TMEM217 | c.211C>T p.L71= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV100362666; called by muse, mutect2, varscan2
- TMTC2 | c.777C>T p.P259= | Silent (SNP) | VAF 37/241 reads (15%) | catalogued as rs757222007, COSV58280384; called by muse, mutect2, varscan2
- TNN | c.330C>A p.A110= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs759272100, COSV99512741; called by muse, mutect2, varscan2
- TPRG1L | c.597A>C p.A199= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV99573475; called by muse, mutect2, varscan2
- TRPV3 | c.1992C>G p.L664= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- TRRAP | c.6889C>T p.L2297= (on ENST00000359863 / NM_001244580.1; = p.L2279= on NM_003496.3) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100722813; called by muse, mutect2, varscan2
- UBAP2L | c.3126G>A p.P1042= | Silent (SNP) | VAF 57/289 reads (20%) | catalogued as rs777218806, COSV55167211; called by muse, mutect2, varscan2
- UNC45B | c.1663C>T p.L555= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99268405; called by muse, mutect2, varscan2
- ZBTB2 | c.1437C>T p.D479= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs549133340, COSV57311849; called by muse, mutect2, varscan2
- ZNF251 | c.864T>A p.T288= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99478777; called by muse, mutect2, varscan2
- ZNF366 | c.600G>A p.R200= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100574399; called by muse, mutect2, varscan2
- ZNF396 | c.501C>G p.L167= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100108637; called by muse, mutect2, varscan2
- ZSWIM4 | c.1152C>T p.S384= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99585324; called by muse, mutect2, varscan2
- BRSK2 | c.1227-1925G>T | Intron (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100373042; called by muse, mutect2, varscan2
- HTR2C | c.-79-11592G>T | Intron (SNP) | VAF 34/54 reads (63%) | catalogued as COSV52212687; called by muse, mutect2, varscan2
- KIF1B | c.2115+6054T>G | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99824018; called by muse, mutect2, varscan2
- MIR517B | n.24G>C | RNA (SNP) | VAF 32/140 reads (23%) | catalogued as rs1243018013; called by muse, mutect2, varscan2
- NCAM1 | c.-127T>C | 5'UTR (SNP) | VAF 7/13 reads (54%) | catalogued as COSV101207565; called by muse, mutect2, varscan2
- OBSCN | c.4585+2802A>C | Intron (SNP) | VAF 20/125 reads (16%) | catalogued as COSV99477068, COSV99482951; called by muse, mutect2, varscan2
- PEAK3 | c.-1C>G | 5'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100574365, COSV59700720; called by muse, mutect2, varscan2
- SRSF6 | c.257-554G>A | Intron (SNP) | VAF 11/42 reads (26%) | catalogued as rs776429265; called by muse, mutect2, varscan2
- SSPOP | n.3292C>A | RNA (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100022885; called by muse, mutect2
- SYTL2 | c.1459+3041A>T | Intron (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100314746; called by muse, mutect2, varscan2
